Gene-level copy-number profile of specimen HCM-CSHL-0622-C18-85A from HCMI case HCM-CSHL-0622-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: GX; Age at diagnosis: 78.3 years (28,592 days).
Specimen HCM-CSHL-0622-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8e37a815-8465-4b00-a1b7-4e1f0260bcc5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0622-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/d1d07b3d-fe6b-485c-9c5d-8cc553f1569e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 762; copy number 2: 19,281; copy number 3: 28,734; copy number 4: 8,839; copy number 5: 19; copy number 6: 161; copy number 7: 567; copy number 8: 7; copy number 9: 26.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 600 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:182,598,623–183,472,265, 22 genes, copy number 8–9 (within-gene range 4–9): RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1.
- chr5:58,198–3,181,487, 84 genes, copy number 7–8 (broad region; genes not listed).
- chr5:4,012,708–6,030,841, 27 genes, copy number 7: AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC010266.2, AC010266.1.
- chr5:6,310,441–6,378,571, 2 genes, copy number 7: LINC02145, MED10.
- chr5:6,765,891–6,833,120, 1 gene, copy number 7 (within-gene range 6–7): LINC02236.
- chr5:6,839,460–7,219,291, 5 genes, copy number 7: LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1.
- chr5:7,396,138–12,804,363, 92 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:12,914,068–14,961,393, 23 genes, copy number 7: LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1.
- chr5:16,373,361–18,236,196, 59 genes, copy number 7: LINC02150, AC020980.1, ZNF622, RETREG1, AC024588.1, AC022113.1, Y_RNA, MYO10, RNA5SP179, RPS26P28, RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218, H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223, RPL36AP21, SNORD81.
- chr5:18,886,622–19,142,346, 7 genes, copy number 7: UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14.
- chr5:19,471,296–20,575,873, 4 genes, copy number 7: CDH18, AC093303.1, AC094103.1, CDH18-AS1.
- chr5:21,750,673–22,853,344, 1 gene, copy number 7 (within-gene range 6–7): CDH12.
- chr5:22,212,476–25,324,386, 33 genes, copy number 7 (within-gene range 4–7): AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, CDH10, AC091885.2, AC091885.1, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1.
- chr5:26,880,597–28,809,291, 7 genes, copy number 7 (within-gene range 6–7): CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1.
- chr5:28,808,538–30,365,684, 20 genes, copy number 7: AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1.
- chr5:31,400,497–33,298,066, 43 genes, copy number 7 (within-gene range 6–7): DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160.
- chr5:33,502,072–39,721,513, 104 genes, copy number 7 (broad region; genes not listed).
- chr5:39,892,138–40,984,643, 15 genes, copy number 7: LINC00603, KRT18P56, LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1.
- chr5:43,013,060–43,886,628, 29 genes, copy number 7: AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1.
- chr5:44,300,247–45,696,498, 13 genes, copy number 7: FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1.
- chr20:52,972,358–53,495,330, 1 gene, copy number 9 (within-gene range 4–9): TSHZ2.
- chr20:53,137,293–53,544,725, 8 genes, copy number 9: AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 762. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
